Surgical pathology report (de-identified scan), TCGA case TCGA-24-2026, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Washington University, specimen TCGA-24-2026-01A (Primary Tumor).

[page 1 of 4]
Name: [REDACTED]
Address: [REDACTED]

MR No.: [REDACTED]
Service: [REDACTED]
Surgeon: [REDACTED]

Surg. Path. No.: [REDACTED]
DOB: [REDACTED]
Sex/Race: [REDACTED]
Location: [REDACTED]
Hosp. No.: [REDACTED]
Taken/Received: [REDACTED]

DIAGNOSIS

TCGA-24-2026

OVARIES, RIGHT AND LEFT, BILATERAL OOPHORECTOMY
- POORLY DIFFERENTIATED SEROUS ADENOCARCINOMA

UTERUS, SEROSA AND MYOMETRIUM, HYSTERECTOMY
- SEROSAL AND LYMPHATIC INVOLVEMENT BY METASTATIC
CARCINOMA
- LEIOMYOMATA

UTERUS, ENDOMETRIUM, HYSTERECTOMY - MICROSCOPIC FOCUS OF WELL
DIFFERENTIATED ENDOMETRIOID ADENOCARCINOMA ARISING
IN AN ENDOMETRIAL POLYP (SEE COMMENT)

SOFT TISSUE, OMENTUM, EXCISION - METASTATIC ADENOCARCINOMA
CONSISTENT WITH OVARIAN PRIMARY

FALLOPIAN TUBES, RIGHT AND LEFT, BILATERAL SALPINGECTOMY
- NO HISTOPATHOLOGIC ABNORMALITY

SPECIMEN(S) SUBMITTED

- Part 1: RIGHT SALPINGO OOPHORECTOMY
- Part 2: LEFT SALPINGO OOPHORECTOMY
- Part 3: UTERUS
- Part 4: OMENTUM

HISTORY

The patient is a [REDACTED] with bilateral adnexal masses.
Clinical diagnosis: Not stated. Operative procedure: Total
abdominal hysterectomy, bilateral salpingo-oophorectomy and
omentectomy.

GROSS

The specimens are received in four containers of formalin, each
labelled with the patient's name. The first container is labelled
"right salpingo-oophorectomy" and contains a salpingo-oophorectomy
specimen which is markedly enlarged measuring 6.5 x 5.5 x 3.0 cm

[page 2 of 4]
[REDACTED]
Surg. Path. No.:

Name: [REDACTED]

GROSS (continued).

in maximum dimensions. The attached fallopian tube measures 5 cm in length and 0.5 cm in average diameter. It includes the fimbriated end and it has been previously transected at its mid portion. The serosal surface is pink-tan and smooth and grossly unremarkable. The attached ovary is markedly enlarged and partially cystic measuring 5.5 x 4.5 x 4 cm in maximum dimensions. Cross sections show a solid and cystic tumor with numerous papillary excrescences as well as solid areas, which comprise more than 50% of the specimen grossly. The tumor extends onto the serosal surface grossly and appears to invade the mesovarium. No residual ovarian tissue can be identified with certainty. There is no gross evidence of tubal involvement by tumor. Labelled A1 to A7 - ovary; A8 - fallopian tube. Jar 1.

The second container is labelled "left salpingo-oophorectomy" and contains a salpingo-oophorectomy specimen which is markedly enlarged 7 x 5.5 x 5 cm in maximum dimensions. The attached fallopian tube which includes the fimbriated end measures 8 cm in length and 0.7 in average diameter. Adherent tumor is identified on the serosal surface. Cross sections to the lumen show the attached ovary is markedly distorted by a tan-white papillary and cystic tumor which is noted to extend diffusely over the serosal surface. Cut surfaces of the tumor show that it is pink-white and primarily solid with areas of papillation and nodularity. The solid portions of the tumor comprise less than 50% of its mass grossly. Labelled B1 to B7 - left ovary; B8 - left fallopian tube. Jar 1.

The third container is labelled "uterus" and contains a markedly distorted fragment of tan-white nodular muscular tissue measuring 7.5 x 7 x 5 cm in maximum dimension. The cervix cannot be identified. A markedly distorted and shrunken endometrial cavity measuring 1.5 x 1 cm is tentatively identified. Very little serosal surface is remaining. The serosal surface is partially covered by tan-white papillary tissue grossly consistent with the tumor seen in the ovarian specimens. In addition, the specimen is markedly distorted by subserosal and intramural leiomyomas which range from 0.5 to 2.2 cm in greatest diameter. Each has a firm, white, whorled appearance without necrosis or hemorrhage. Labelled C1 and C2 - endometrium; C3 to C6 - myomas; C7 and C8 - tumor, extending to uterus. Jar 2.

The fourth container is labelled "omentum" and contains a single

[page 3 of 4]
Name:

Surg. Path. No.:

GROSS (continued)

Irregularly-shaped fragment of tan-white-yellow hemorrhagic lobulated adipose tissue measuring 24 x 12 x 5 cm in maximum dimensions. The omentum is extensively grossly involved by metastatic tumor. Labelled D1 to D4, Jar 2.

COMMENT

Histologic sections of both ovaries are notable for a poorly differentiated serous adenocarcinoma. The tumor shows papillary as well as focal (<5%) clear cell change. Tumor is also identified within the omentum and on the serosal surface of the uterus. Uterine lymphatic invasion is also seen. Histologic sections of the endometrium show a microscopic focus of well differentiated endometrioid adenocarcinoma which appears to arise in an endometrial polyp and in an area immediately adjacent to the polyp. This tumor does not show evidence of myometrial invasion and is morphologically different from the ovarian tumor and, therefore, does not represent a metastatic implant from the latter. Due to the highly distorted nature of the uterus, no cervix could be definitively identified, and only a small portion of the endometrial cavity (which included the polyp) was identified.

SYNOPTIC REPORTING FORM FOR MALIGNANT OVARIAN NEOPLASMS

- 1a. A neoplasm is PRESENT.
2. The HISTOLOGIC DIAGNOSIS is:
Serous adenocarcinoma
3. The LOCATION(S) OF THE PRIMARY TUMOR(S) is/are:
Right and left ovary (synchronous primary tumors)
4. The FIGO GRADE of the tumor is:
III (Tumor composed of greater than 80% solid cellular nests)
5. The NUCLEAR (BRODERS') GRADE of the tumor is:
G3 (Poorly-differentiated)
6. Tumor IS identified on the ovarian surface(s).
7. Tumor DOES invade the mesovarium.
8. Tumor DOES NOT invade the adjacent fallopian tube.
9. Tumor DOES invade the pelvic soft tissue.
10. Tumor involvement of the pelvic peritoneum is PRESENT.
11. Metastatic involvement of the EXTRAPELVIC peritoneum is PRESENT.
12. Metastatic involvement of the omentum is PRESENT.
13. The maximum dimension of tumor implants outside the true

[page 4 of 4]
Surg. Path. No.:

1

Name:

COMMENT (continued)

- pelvis is not evaluable (entire omental biopsy involved)
14. Metastatic involvement of the uterine serosa is PRESENT.
15. Metastatic involvement of the endometrium is ABSENT.
16. Regional lymph node metastases CANNOT BE EVALUATED.
17. The total number of regional lymph nodes examined is 0.
18. The total number of metastatically-involved regional lymph nodes is 0.

19. DETAILED STAGING INFORMATION:

Based on the above information, the PRIMARY TUMOR is classified as:

TNM SCHEME	FIGO SCHEME	DEFINITION
T3c	IIIC	Macroscopic peritoneal metastasis beyond true pelvis measuring greater than 2 cm in greatest dimension

THE REGIONAL LYMPH NODES are classified as:

NX (Nodal status cannot be assessed)

THE STATUS OF DISTANT TUMOR SITES is classified as:

MX (Status cannot be assessed)

20. The FINAL AJCC/FIGO STAGE IS:

AJCC SCHEME	FIGO SCHEME
3c	IIIC

{End of Report}

Source: NCI Genomic Data Commons file 30e5ed9a-5a58-4121-97f8-b4e8a61c6147 (TCGA-24-2026.7FC3CF2F-B132-4DCE-B16A-2B4A1162DA14.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).